Somatic mutation profile of tumor specimen MP2PRT-PASEZC-TBP1-A (aliquot MP2PRT-PASEZC-TBP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASEZC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.4 years (4,511 days).
Specimen MP2PRT-PASEZC-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62d72a3a-f4b1-4143-9ba2-3b6a1e5df816.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASEZC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASEZC-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1691af6-5a7a-411d-abac-d54baef8694e

The open-access MAF lists 95 somatic variants for this specimen: 75 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 65, Silent 20, Nonsense Mutation 8, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHR | c.2173G>C p.E725Q | Missense Mutation (SNP) | VAF 12/352 reads (3%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV99619720; called by muse, mutect2
- ANK1 | c.5233G>A p.G1745S | Missense Mutation (SNP) | VAF 36/628 reads (6%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0); catalogued as rs765493524; called by muse, mutect2
- ARMC5 | c.644G>A p.S215N | Missense Mutation (SNP) | VAF 58/615 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1340928846; called by muse, mutect2
- CASK | c.1084G>C p.D362H | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV59372532; called by muse, mutect2, varscan2
- CASP5 | c.108G>T p.K36N | Missense Mutation (SNP) | VAF 17/319 reads (5%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.141); catalogued as COSV99507443; called by muse, mutect2
- CFAP47 | c.2746G>A p.E916K | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773028112, COSV52882975; called by muse, mutect2, varscan2
- DLX5 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 37/683 reads (5%) | catalogued as COSV56033490; called by muse, mutect2
- FAM181B | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 53/797 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs780433938, COSV100235010; called by muse, mutect2
- FNBP4 | c.994G>C p.E332Q | Missense Mutation (SNP) | VAF 15/396 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV55446986, COSV55449457; called by muse, mutect2
- GPR27 | c.71C>T p.T24M | Missense Mutation (SNP) | VAF 54/736 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.212); catalogued as COSV55202830; called by muse, mutect2
- KRTAP25-1 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV68914295; called by muse, mutect2
- LNX1 | c.1033C>T p.R345W (on ENST00000263925 / NM_001126328.3; = p.R249W on NM_032622.2) | Missense Mutation (SNP) | VAF 40/435 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs763938904; called by muse, mutect2
- MOXD1 | c.1421G>A p.R474K | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.098); catalogued as rs1286558079, COSV60948979; called by muse, mutect2
- MUC16 | c.31199G>C p.R10400T | Missense Mutation (SNP) | VAF 42/434 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.574); catalogued as COSV67464408; called by muse, mutect2
- NDC80 | c.381G>C p.K127N | Missense Mutation (SNP) | VAF 11/338 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV55247302; called by muse, mutect2
- OR5M1 | c.260C>G p.S87* | Nonsense Mutation (SNP) | VAF 19/444 reads (4%) | catalogued as COSV101591530; called by muse, mutect2
- SLC25A31 | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 27/353 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV55417690, COSV55418534; called by muse, mutect2
- SLC35G5 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 57/697 reads (8%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs201648774; called by muse, mutect2
- TMEM163 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs759386524, COSV56106811; called by muse, mutect2
- TMEM169 | c.416C>G p.S139* | Nonsense Mutation (SNP) | VAF 16/437 reads (4%) | catalogued as COSV55267181; called by muse, mutect2
- TNIK | c.2541G>C p.E847D | Missense Mutation (SNP) | VAF 27/507 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.074); catalogued as rs1475322502, COSV99458518; called by muse, mutect2
- TTC6 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 47/727 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.645); catalogued as rs1355552812; called by muse, mutect2
- UBA2 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 14/295 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); catalogued as rs1191303451; called by muse, mutect2
- VARS1 | c.3127G>A p.E1043K | Missense Mutation (SNP) | VAF 31/800 reads (4%) | SIFT tolerated (0.9); PolyPhen benign (0.007); catalogued as COSV63304151; called by muse, mutect2
- VARS1 | c.1471G>T p.D491Y | Missense Mutation (SNP) | VAF 24/468 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100989920; called by muse, mutect2
- VPS13A | c.8872G>A p.E2958K | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1563967454; called by muse, mutect2
- WNK2 | c.6218G>A p.R2073H (on ENST00000297954 / NM_001282394.1; = p.R2036H on NM_006648.3) | Missense Mutation (SNP) | VAF 36/383 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.013); catalogued as rs776503070, COSV52938847; called by muse, mutect2
- ZNF212 | c.22C>G p.R8G | Missense Mutation (SNP) | VAF 38/693 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.238); catalogued as COSV60025308; called by muse, mutect2
- ACOT4 | c.343G>C p.E115Q | Missense Mutation (SNP) | VAF 32/572 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2
- AGPS | c.563-1G>A p.X188_splice | Splice Site (SNP) | VAF 14/119 reads (12%) | called by muse, mutect2, varscan2
- AMOTL2 | c.1792C>G p.L598V | Missense Mutation (SNP) | VAF 14/495 reads (3%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.493); called by muse, mutect2
- ANO5 | c.1285G>C p.E429Q | Missense Mutation (SNP) | VAF 34/375 reads (9%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.993); called by muse, mutect2
- ARHGAP35 | c.75G>C p.E25D | Missense Mutation (SNP) | VAF 18/453 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); called by muse, mutect2
- ARHGAP35 | c.823G>C p.D275H | Missense Mutation (SNP) | VAF 16/345 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); called by muse, mutect2
- BICDL2 | c.446C>T p.A149V | Missense Mutation (SNP) | VAF 69/846 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- C2CD3 | c.3652G>A p.E1218K | Missense Mutation (SNP) | VAF 11/320 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); called by muse, mutect2
- C9orf40 | c.211A>C p.S71R | Missense Mutation (SNP) | VAF 44/904 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.112); called by muse, mutect2
- CCDC15 | c.2671G>C p.D891H | Missense Mutation (SNP) | VAF 14/486 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2
- CTC1 | c.1963G>C p.E655Q | Missense Mutation (SNP) | VAF 36/329 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- EGLN2 | c.46C>T p.Q16* | Nonsense Mutation (SNP) | VAF 18/502 reads (4%) | called by muse, mutect2
- EIF3B | c.908G>A p.R303K | Missense Mutation (SNP) | VAF 18/436 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.07); called by muse, mutect2
- FAM160A1 | c.1866G>C p.K622N | Missense Mutation (SNP) | VAF 24/407 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- FOSB | c.799C>T p.Q267* | Nonsense Mutation (SNP) | VAF 28/783 reads (4%) | called by muse, mutect2
- FRMPD2 | c.82C>G p.L28V | Missense Mutation (SNP) | VAF 21/496 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- HEPHL1 | c.1230C>A p.G410= | Splice Region (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- HMCN1 | c.3853G>A p.E1285K | Missense Mutation (SNP) | VAF 17/397 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.037); called by muse, mutect2
- MARCKS | c.480C>G p.F160L | Missense Mutation (SNP) | VAF 17/608 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); called by muse, mutect2
- MED13L | c.1364C>G p.S455* | Nonsense Mutation (SNP) | VAF 21/487 reads (4%) | called by muse, mutect2
- MUC16 | c.30858G>C p.M10286I | Missense Mutation (SNP) | VAF 21/255 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); called by muse, mutect2
- MYH10 | c.2408G>A p.R803K | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- NLRP8 | c.1660C>G p.H554D | Missense Mutation (SNP) | VAF 13/327 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.191); called by muse, mutect2
- NUDCD1 | c.1598G>A p.R533K | Missense Mutation (SNP) | VAF 39/472 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- NUTM2D | c.1441G>A p.E481K | Missense Mutation (SNP) | VAF 4/134 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.55); called by muse, mutect2
- PAQR8 | c.637C>G p.Q213E | Missense Mutation (SNP) | VAF 24/499 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAQR8 | c.930C>G p.I310M | Missense Mutation (SNP) | VAF 12/404 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2
- PDE4DIP | c.231G>C p.E77D | Missense Mutation (SNP) | VAF 7/241 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); called by muse, mutect2
- PIAS1 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 17/311 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- PKHD1L1 | c.7814G>C p.R2605T | Missense Mutation (SNP) | VAF 13/346 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.097); called by muse, mutect2
- PPP1R37 | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 19/465 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); called by muse, mutect2
- RPL37A | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 15/392 reads (4%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- SEPTIN3 | c.135C>A p.D45E | Missense Mutation (SNP) | VAF 27/563 reads (5%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.967); called by muse, mutect2
- SIGLEC5 | c.1239G>A p.W413* | Nonsense Mutation (SNP) | VAF 15/425 reads (4%) | called by muse, mutect2
- SLC2A2 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.434); called by muse, mutect2
- SMARCA5 | c.640C>G p.Q214E | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SPNS2 | c.163G>C p.D55H | Missense Mutation (SNP) | VAF 27/733 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.283); called by muse, mutect2
- ST7L | c.379G>C p.E127Q | Missense Mutation (SNP) | VAF 17/517 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.143); called by muse, mutect2
- TET2 | c.5872G>A p.E1958K | Missense Mutation (SNP) | VAF 20/524 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- TGOLN2 | c.1143G>C p.E381D | Missense Mutation (SNP) | VAF 32/538 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- TINAG | c.480A>C p.L160F | Missense Mutation (SNP) | VAF 26/283 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TOX3 | c.648C>G p.I216M | Missense Mutation (SNP) | VAF 13/322 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); called by muse, mutect2
- UNC13A | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 24/692 reads (3%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.037); called by muse, mutect2
- WDR19 | c.3661G>C p.E1221Q | Missense Mutation (SNP) | VAF 18/516 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- WDR87 | c.2293C>T p.Q765* | Nonsense Mutation (SNP) | VAF 18/498 reads (4%) | called by muse, mutect2
- Z83844.2 | c.1720G>C p.E574Q | Missense Mutation (SNP) | VAF 24/636 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.8); called by muse, mutect2
- ZNF839 | c.517G>A p.E173K (on ENST00000558850 / NM_001267827.1; = p.E289K on NM_018335.5) | Missense Mutation (SNP) | VAF 15/231 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ARHGAP35 | c.1404G>A p.L468= | Silent (SNP) | VAF 16/237 reads (7%) | called by muse, mutect2
- ARHGEF2 | c.444G>A p.K148= (on ENST00000361247 / NM_001162383.2; = p.K121= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 16/332 reads (5%) | called by muse, mutect2
- ATP12A | c.2361C>G p.L787= | Silent (SNP) | VAF 28/396 reads (7%) | called by muse, mutect2
- CA4 | c.459G>C p.V153= | Silent (SNP) | VAF 43/450 reads (10%) | called by muse, mutect2
- CADPS2 | c.111T>C p.T37= | Silent (SNP) | VAF 48/796 reads (6%) | called by muse, mutect2
- CTR9 | c.663C>T p.F221= | Silent (SNP) | VAF 27/456 reads (6%) | called by muse, mutect2
- DACH1 | c.579G>C p.L193= | Silent (SNP) | VAF 32/521 reads (6%) | called by muse, mutect2
- FRG2 | c.624A>G p.T208= | Silent (SNP) | VAF 27/383 reads (7%) | called by muse, mutect2, varscan2
- KRT6A | c.105C>T p.S35= | Silent (SNP) | VAF 92/838 reads (11%) | catalogued as rs779059221; called by muse, mutect2, varscan2
- MROH2B | c.2595C>T p.S865= | Silent (SNP) | VAF 13/367 reads (4%) | catalogued as COSV68189364; called by muse, mutect2
- NOL6 | c.1188C>T p.L396= | Silent (SNP) | VAF 13/393 reads (3%) | called by muse, mutect2
- OR14A2 | c.897G>C p.L299= | Silent (SNP) | VAF 12/324 reads (4%) | catalogued as rs1183037292; called by muse, mutect2
- OR2Z1 | c.108C>A p.V36= | Silent (SNP) | VAF 26/590 reads (4%) | called by muse, mutect2
- PLEKHG2 | c.3507C>T p.L1169= | Silent (SNP) | VAF 24/588 reads (4%) | called by muse, mutect2
- PRR5 | c.775C>T p.L259= (on ENST00000336985 / NM_181333.4; = p.L250= on NM_015366.4) | Silent (SNP) | VAF 26/627 reads (4%) | called by muse, mutect2
- PRSS8 | c.36G>C p.L12= | Silent (SNP) | VAF 45/566 reads (8%) | called by muse, mutect2
- PSD2 | c.2271G>A p.V757= | Silent (SNP) | VAF 14/400 reads (4%) | called by muse, mutect2
- RELN | c.1560G>A p.P520= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as rs41276157; called by muse, mutect2, varscan2
- SERPINA7 | c.345G>C p.L115= | Silent (SNP) | VAF 16/314 reads (5%) | catalogued as COSV59665449; called by muse, mutect2
- TRIM6-TRIM34 | c.2403C>T p.F801= | Silent (SNP) | VAF 17/379 reads (4%) | catalogued as COSV61457642; called by muse, mutect2
